Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAIR, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAIR-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: [REDACTED] (Age: [REDACTED] Gender: M
Requested By: [REDACTED]

Accession #:
Procedure Date:
Received Date:
Account #:
Report Signed: [REDACTED]

Final Diagnosis:

- A. Right external iliac lymph nodes, lymph node dissection:
Four (4) benign reactive lymph nodes, negative for malignancy.
- B. Right obturator and internal iliac lymph nodes, lymph node dissection:
Two (2) benign reactive lymph nodes, negative for malignancy.
- C. Left external iliac lymph node dissection:
Two (2) benign reactive lymph nodes, negative for malignancy.
- D. Left obturator and internal iliac lymph node, lymph node dissection:
Two (2) benign reactive lymph nodes, negative for malignancy.
- E. Prostate, radical prostatectomy:
Prostatic adenocarcinoma, Gleason score 4+4=8.
See synoptic report.

ICD-O-3
Adenocarcinoma NOS
S140/3
Site Prostate NOS
061.9
7/0 3/25/14

Procedure: Radical prostatectomy.

Histologic type: Prostatic adenocarcinoma, acinar type.

Histologic grade:

Primary pattern: 4, Secondary pattern: 4.

Total Gleason Score: 8.

Tumor quantitation and location: Tumor is present bilaterally in the apex and midprostate, and involves approximately 35% of the sampled prostate tissue by volume.

Extraprostatic extension: Not identified.

Margins: Negative for carcinoma.

Lymph-vascular invasion: Not identified.

Perineural invasion: Present.

Seminal vesicle invasion: Not identified.

Treatment effect on carcinoma: Not identified.

Lymph nodes: Ten (10) total lymph nodes (specimens A through D), all negative for carcinoma.

Additional pathologic findings: None.

Ancillary studies: Available upon request.

Pathologic staging: pT2c, N0 (AJCC 7th Edition).

[page 2 of 3]
Biorepository sample (if applicable): Block E17 containing 70% tumor (Gleason 4+4=8).
Block(s) containing malignancy suitable for additional testing: E8, E10.

Interpreted by:

Report electronically signed out by

Transcribed by:

Clinical Information:

Prostate cancer.

Specimen(s):

A: Right external iliac lymph nodes
B: Right obturator and internal iliac lymph nodes
C: Left external iliac lymph node
D: Left obturator and internal iliac lymph node
E: Prostate

Gross Description:

Performed by:

Pathologist's Assistant

A1A2B1B2C1C2D1D2E1E2E3E4E5E6E7E8E9E10E11E12E13E14E15E16E17

A. Received fresh labeled " " and "right external iliac pelvic nodes" is a 5.2-cm piece of fibrofatty tissue. Within the fatty tissue are four possible lymph nodes, the largest is up to 2 cm in maximum dimension. All of the lymph nodes are submitted in two cassettes labeled A1) three lymph nodes; A2) one lymph node.

B. Received fresh labeled " " and "right obturator and internal iliac lymph node." Within the adipose tissue are two lymph nodes, the largest is up to 2 cm. in maximum dimension. All of the lymph nodes are submitted in cassettes labeled B1) one lymph node, bisected; B2) one lymph node, bisected.

C. Received fresh labeled " " and "left external iliac lymph nodes" are two pieces of adipose tissue aggregating to 3.5 x 3 x 0.8 cm. Within the adipose tissue are two possible fatty lymph nodes. All of the tissue is submitted in cassettes labeled C1) one possible lymph node and fat; C2) one possible lymph node and fat.

D. Received fresh labeled " " and "left obturator and internal iliac lymph nodes" are two pieces of adipose tissue aggregating to 3.5 x 2.5 x 1 cm. Within the adipose tissue are two lymph nodes, the largest is up to 2.2 cm. in maximum dimension. All of the lymph nodes are submitted in two cassettes labeled D1) one lymph node, bisected; D2) larger lymph node, bisected.

E. Received fresh labeled " " and "prostate".

Procedure: Radical prostatectomy.

Prostate size: Weight: 53 grams; Dimensions: 5 x 5 x 4.8 cm; Seminal vesicles: 1.7 x 1.5 x 0.8 cm.

Gross notes: Grossly evident tumor: Yes, 0.8 x 0.8 x 0.5 cm, right mid-base.

Symmetry: Asymmetrical. The right is slightly larger than the left.

Gross nodular hyperplasia: Moderate.

Gross capsular bulge/defect: None.

Inking: left-black, right-blue

Biorepository sample collected: Yes. See block key summary.

Lymph nodes: No lymph nodes present.

Block key for specimen E:

[page 3 of 3]
- 1) proximal urethral margin
2) distal urethral margin
3) left apical margin, perpendicular
4) right apical margin, perpendicular
5) left bladder neck margin, perpendicular
6) right bladder neck margin, perpendicular
7) left apical prostate
8) right apical prostate
9) left mid prostate
10) right mid prostate
11) left mid prostate
12) right mid prostate
13) left base of prostate
14) right base of prostate
15) left seminal vesicle
16) right seminal vesicle

Additional sections:

- 17) mirror image of tissue corresponding to research

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by
They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is
not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as
qualified to perform high complexity clinical laboratory testing

END OF REPORT

Source: NCI Genomic Data Commons file 6fdf39a5-9590-42cd-b942-04663453e265 (TCGA-XK-AAIR.72784D06-D1DA-4E0C-B378-771030D57046.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).